Somatic mutation profile of tumor specimen TCGA-23-1021-01B (aliquot TCGA-23-1021-01B-01W-0488-09) from TCGA case TCGA-23-1021, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 45.1 years (16,484 days).
Specimen TCGA-23-1021-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f6e6d9b-a683-4593-84ad-6fe77f9294fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1021-10A (Blood Derived Normal), aliquot TCGA-23-1021-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/020726c8-5676-4d5f-b840-e59a28006912

The open-access MAF lists 106 somatic variants for this specimen: 80 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 23, Nonsense Mutation 4, In Frame Del 3, Frame Shift Del 3, Splice Site 2, Intron 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 56/78 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AOC1 | c.644C>A p.T215N | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1283724554, COSV100711103, COSV62867841; called by muse, mutect2, varscan2
- ARL10 | c.648G>C p.L216F | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.955); catalogued as COSV59990354; called by muse, mutect2, varscan2
- BMS1 | c.1204G>T p.G402W | Missense Mutation (SNP) | VAF 163/341 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV65733512; called by muse, mutect2, varscan2
- CDH7 | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 96/116 reads (83%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59883836; called by muse, mutect2, varscan2
- CEP70 | c.349C>A p.Q117K | Missense Mutation (SNP) | VAF 58/314 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV99388905; called by muse, mutect2, varscan2
- CEP95 | c.1234G>C p.D412H | Missense Mutation (SNP) | VAF 67/81 reads (83%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as COSV73608940; called by muse, mutect2, varscan2
- CLCN5 | c.785T>A p.V262E | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56583201; called by muse, mutect2, varscan2
- CLIP3 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); catalogued as rs1185240143, COSV53324352; called by muse, mutect2, varscan2
- COL4A4 | c.1248_1256del p.L418_G420del | In Frame Del (DEL) | VAF 19/62 reads (31%) | catalogued as rs762759315; called by mutect2, pindel, varscan2
- COL7A1 | c.8630C>A p.S2877Y | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.255); catalogued as COSV99866144; called by muse, mutect2, varscan2
- DCK | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 55/72 reads (76%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV54378107; called by muse, mutect2, varscan2
- DGKA | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 144/320 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59385406; called by muse, mutect2, varscan2
- DHX34 | c.1272+1G>C p.X424_splice | Splice Site (SNP) | VAF 4/8 reads (50%) | catalogued as COSV60894979; called by muse, mutect2
- DZIP1 | c.944T>A p.L315* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as COSV61264942; called by muse, mutect2, varscan2
- FAM184A | c.1870G>C p.E624Q | Missense Mutation (SNP) | VAF 65/83 reads (78%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.639); catalogued as COSV58853134, COSV58857324; called by muse, mutect2, varscan2
- FLNC | c.1179C>G p.N393K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs547934558, COSV100367713; called by muse, mutect2, varscan2
- FOSL2 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV53103943; called by muse, mutect2, varscan2
- GNB4 | c.381G>T p.K127N | Missense Mutation (SNP) | VAF 28/488 reads (6%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); catalogued as COSV51710634; called by muse, mutect2
- H4C13 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.243); catalogued as COSV60693721; called by muse, mutect2, varscan2
- HTR2A | c.1192C>G p.Q398E | Missense Mutation (SNP) | VAF 132/153 reads (86%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV66327010; called by muse, mutect2, varscan2
- HYI | c.565G>A p.D189N (on ENST00000372434 / NM_001330526.2; = p.D164N on NM_031207.6) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.209); catalogued as rs373445250, COSV65094357; called by muse, mutect2, varscan2
- IGLV3-12 | c.203G>A p.S68N | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1395555937; called by muse, mutect2, varscan2
- IRS4 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV64533199; called by muse, mutect2, varscan2
- JRK | c.281A>C p.Y94S | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as COSV101401057; called by muse, mutect2, varscan2
- KEL | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 268/464 reads (58%) | SIFT tolerated (0.96); PolyPhen benign (0.012); catalogued as COSV62334233; called by muse, mutect2, varscan2
- LAMA3 | c.6888C>A p.N2296K (on ENST00000313654 / NM_198129.4; = p.N687K on NM_000227.6) | Missense Mutation (SNP) | VAF 70/97 reads (72%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs141023743, COSV52532750; called by muse, mutect2, varscan2
- LAMB1 | c.4310C>T p.A1437V | Missense Mutation (SNP) | VAF 153/344 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as COSV55963349; called by muse, mutect2, varscan2
- LCP2 | c.1178C>A p.A393D | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV50448390; called by muse, mutect2, varscan2
- LINS1 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs117825322, COSV59078498; called by muse, mutect2
- LRRC15 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0.027); catalogued as rs200640377; called by muse, mutect2, varscan2
- MACROD2 | c.695A>C p.Y232S | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53966677; called by muse, mutect2, varscan2
- MYO18A | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs372515961; called by muse, mutect2, varscan2
- MYO9B | c.2089G>C p.V697L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV68278228; called by muse, mutect2, varscan2
- NIBAN1 | c.2183C>G p.P728R | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as COSV62284141; called by muse, mutect2, varscan2
- NIBAN1 | c.2182C>A p.P728T | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.035); catalogued as COSV100836394, COSV62284147; called by muse, mutect2, varscan2
- NMT2 | c.1044C>G p.I348M | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.21); catalogued as COSV65381906; called by muse, mutect2, varscan2
- NOL4 | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV52343704; called by muse, mutect2, varscan2
- OR11H12 | c.107G>A p.W36* | Nonsense Mutation (SNP) | VAF 187/385 reads (49%) | catalogued as rs1277115750, COSV73543557, COSV73543756; called by muse, mutect2, varscan2
- OR8U1 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 343/1070 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776653874, COSV56415051; called by muse, varscan2
- PHLPP2 | c.316A>T p.I106F | Missense Mutation (SNP) | VAF 44/58 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100673549; called by muse, mutect2, varscan2
- PHLPP2 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100673550; called by muse, mutect2, varscan2
- PIKFYVE | c.2756C>A p.P919H | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV52239292; called by muse, mutect2, varscan2
- PKN1 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52874855; called by muse, mutect2, varscan2
- RASA2 | c.407C>G p.T136S | Missense Mutation (SNP) | VAF 61/365 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.118); catalogued as COSV53938261; called by muse, mutect2, varscan2
- RIF1 | c.4159A>G p.N1387D | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV54615054; called by muse, mutect2, varscan2
- RWDD1 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.254); catalogued as COSV63972330; called by muse, mutect2, varscan2
- RWDD1 | c.689C>A p.P230Q | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV63972332; called by muse, mutect2, varscan2
- SENP7 | c.1597A>T p.K533* | Nonsense Mutation (SNP) | VAF 48/134 reads (36%) | catalogued as COSV58610244; called by muse, mutect2, varscan2
- SIPA1L1 | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62169421; called by muse, mutect2, varscan2
- SLC22A8 | c.497G>C p.G166A | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV60324417; called by muse, mutect2, varscan2
- SLC35G6 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100262875; called by muse, varscan2
- SLC50A1 | c.524G>A p.W175* | Nonsense Mutation (SNP) | VAF 112/315 reads (36%) | catalogued as COSV57596548; called by muse, mutect2, varscan2
- SLC9A7 | c.934A>C p.T312P | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV60379180; called by muse, mutect2, varscan2
- SMARCD1 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67411884; called by muse, mutect2, varscan2
- SORL1 | c.2183A>G p.Y728C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1423057943, COSV52752156; called by muse, mutect2, varscan2
- SPNS3 | c.604T>A p.W202R | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100336886; called by muse, mutect2, varscan2
- STAT4 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 74/274 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV61829011; called by muse, mutect2, varscan2
- STK38 | c.995A>C p.K332T | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV57708191; called by muse, mutect2, varscan2
- TMEM39A | c.91A>T p.N31Y | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV59900068; called by muse, mutect2, varscan2
- TMEM67 | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV60037734; called by muse, mutect2, varscan2
- TRPM4 | c.1922T>C p.L641P | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53261556; called by muse, mutect2, varscan2
- TSTD2 | c.919C>A p.L307I | Missense Mutation (SNP) | VAF 77/93 reads (83%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV52245726; called by muse, mutect2, varscan2
- UGT1A9 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 398/865 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.232); catalogued as rs1421099141, COSV60835729; called by muse, mutect2, varscan2
- USH2A | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 78/329 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs370653547; called by muse, mutect2, varscan2
- USP19 | c.3166G>A p.G1056S | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1348121120, COSV100025938, COSV60045478; called by muse, mutect2, varscan2
- ZBTB2 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs761712276; called by muse, mutect2
- ZDBF2 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs956527672, COSV65623875, COSV65623909; called by muse, mutect2
- ZFP2 | c.570G>C p.E190D | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV63725361; called by muse, mutect2, varscan2
- ZNF449 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 87/317 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as COSV59346605; called by muse, mutect2, varscan2
- ZNF479 | c.1034G>C p.R345T | Missense Mutation (SNP) | VAF 123/260 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.387); catalogued as COSV58636692, COSV58636789, COSV58637452; called by muse, mutect2, varscan2
- ASH1L | c.6251_6253del p.D2084del (on ENST00000368346 / NM_001366177.2; = p.D2079del on NM_018489.3) | In Frame Del (DEL) | VAF 107/330 reads (32%) | called by mutect2, pindel, varscan2
- ATRX | c.4112_4113del p.R1371Kfs*6 | Frame Shift Del (DEL) | VAF 32/164 reads (20%) | called by mutect2, pindel, varscan2
- CCDC90B | c.317_324+16del p.X106_splice | Splice Site (DEL) | VAF 27/96 reads (28%) | called by mutect2, pindel, varscan2
- HERC4 | c.2450_2473delinsTTTA p.P817Lfs*10 (on ENST00000395198 / NM_022079.3; = p.P809Lfs*10 on NM_015601.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 70/264 reads (27%) | called by pindel, varscan2*
- LNX2 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.908); called by muse, mutect2
- NUP35 | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.217); called by muse, mutect2
- PTPRD | c.1465T>G p.S489A | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.156); called by muse, mutect2
- PTPRM | c.3324_3341del p.I1108_D1113del | In Frame Del (DEL) | VAF 5/37 reads (14%) | called by pindel, varscan2*
- RAB3GAP2 | c.246_247del p.L82Ffs*5 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- ABCC2 | c.4194C>T p.F1398= | Silent (SNP) | VAF 9/194 reads (5%) | called by muse, mutect2
- ARHGAP21 | c.4656G>A p.T1552= | Silent (SNP) | VAF 166/309 reads (54%) | catalogued as rs1267041241, COSV57604354; called by muse, mutect2, varscan2
- CLTCL1 | c.4413G>T p.L1471= | Silent (SNP) | VAF 23/28 reads (82%) | catalogued as COSV54227952; called by muse, mutect2, varscan2
- CYTH4 | c.420C>T p.L140= | Silent (SNP) | VAF 25/29 reads (86%) | catalogued as rs757878344, COSV50631462; called by muse, mutect2, varscan2
- FAIM2 | c.669C>T p.C223= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV57738719; called by muse, mutect2, varscan2
- FAT3 | c.9939C>A p.A3313= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV53094864; called by muse, mutect2, varscan2
- GATA3 | c.525G>A p.S175= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs764256467, COSV60517086; called by muse, mutect2, varscan2
- GMIP | c.1821G>A p.A607= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs748965944, COSV52555338; called by muse, mutect2, varscan2
- HSPA4L | c.121T>C p.L41= | Silent (SNP) | VAF 91/114 reads (80%) | catalogued as rs759617179, COSV56544708; called by muse, mutect2, varscan2
- IRF4 | c.1149G>A p.V383= | Silent (SNP) | VAF 45/51 reads (88%) | catalogued as COSV66704793; called by muse, mutect2, varscan2
- KCNE1 | c.384C>A p.S128= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as rs759950872, COSV61606475; called by mutect2, varscan2
- LRRC37B | c.2499A>G p.T833= | Silent (SNP) | VAF 55/150 reads (37%) | catalogued as COSV58951697; called by muse, mutect2, varscan2
- MTUS1 | c.729C>T p.Y243= | Silent (SNP) | VAF 98/121 reads (81%) | catalogued as rs770552918, COSV50553386; called by muse, mutect2, varscan2
- NLRP13 | c.2058G>A p.K686= | Silent (SNP) | VAF 174/197 reads (88%) | catalogued as rs752440232, COSV61621031; called by muse, mutect2, varscan2
- PCDH7 | c.2964C>T p.G988= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100687712; called by muse, mutect2
- PCED1A | c.603C>T p.P201= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV62313525; called by muse, mutect2, varscan2
- PRAME | c.750G>A p.A250= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as rs376958237; called by muse, mutect2, varscan2
- SLC12A8 | c.405C>A p.A135= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as COSV58865027; called by muse, mutect2, varscan2
- SLC2A3 | c.24A>G p.P8= | Silent (SNP) | VAF 58/125 reads (46%) | catalogued as COSV50001662, COSV99306936; called by muse, mutect2, varscan2
- SPRR3 | c.243T>A p.G81= | Silent (SNP) | VAF 30/240 reads (13%) | catalogued as rs17851565, COSV54878373; called by muse, varscan2
- TTN | c.56541G>T p.V18847= (on ENST00000591111; = p.V11423= on NM_003319.4) | Silent (SNP) | VAF 50/256 reads (20%) | catalogued as COSV59974071; called by muse, mutect2, varscan2
- TUBB | c.1194C>T p.Y398= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV100013288; called by muse, mutect2
- TUT7 | c.2700C>A p.G900= | Silent (SNP) | VAF 72/148 reads (49%) | catalogued as rs778501361, COSV52893413, COSV52894969; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500959 G>T | 5'Flank (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2
- MIR1283-2 | n.39G>T | RNA (SNP) | VAF 187/222 reads (84%) | catalogued as rs752394318; called by muse, mutect2, varscan2
- WLS | c.379+10347C>T | Intron (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99258920; called by muse, mutect2, varscan2
